Somatic mutation profile of tumor specimen TCGA-OR-A5JH-01A (aliquot TCGA-OR-A5JH-01A-11D-A30A-10) from TCGA case TCGA-OR-A5JH, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 32.8 years (11,994 days).
Specimen TCGA-OR-A5JH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7d4a957-4e5b-4c1b-af68-bfebb5313585.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JH-10A (Blood Derived Normal), aliquot TCGA-OR-A5JH-10A-01D-A30A-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/290ce9fd-a397-49c1-b180-6e4575330909

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNB2 | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1219067810; called by muse, mutect2, varscan2
- UBR5 | c.6997C>T p.R2333* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV55288277, COSV55296428; called by muse, varscan2
- GPR137 | c.98T>A p.L33Q | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- GPRASP2 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.046); called by muse, mutect2
- ZPLD1 | c.327+1G>T p.X109_splice (on ENST00000466937 / NM_001329788.1; = p.X125_splice on NM_175056.2) | Splice Site (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- ISX | c.444T>G p.A148= | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as rs1449353210; called by muse, mutect2
- PLXNB3 | c.357G>A p.L119= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs1345329455; called by muse, mutect2, varscan2
- TBX18 | c.1263C>A p.A421= | Silent (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
